Somatic mutation profile of tumor specimen TCGA-ET-A2MX-01A (aliquot TCGA-ET-A2MX-01A-11D-A23M-08) from TCGA case TCGA-ET-A2MX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.5 years (10,044 days).
Specimen TCGA-ET-A2MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe6a53ba-2936-4d7e-828e-123edf8f1ced.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2MX-11C (Solid Tissue Normal), aliquot TCGA-ET-A2MX-11C-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68c91eab-0e7a-4de7-bf25-ea66933ce9ba

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARF | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100247598; called by muse, mutect2
- CEP120 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs755836377, COSV100070978; called by muse, mutect2, varscan2
- DMAC1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.365); catalogued as COSV100830287; called by muse, mutect2, varscan2
- ERF | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1063897, COSV99724596; called by muse, mutect2
- IL17RB | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.438); catalogued as rs1181384155, COSV99213661; called by muse, mutect2
- KMT2D | c.4579G>A p.E1527K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV56497114, COSV99979789; called by muse, mutect2, varscan2
- OR5I1 | c.882G>C p.L294F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100041329, COSV100041775; called by muse, mutect2, varscan2
- RNF113A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV101007021; called by muse, mutect2
- STIM1 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs1565172113, COSV100330626; called by muse, mutect2, varscan2
- DCTD | c.285G>A p.S95= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV63866855; called by muse, mutect2, varscan2
- FLNA | c.6639C>T p.S2213= (on ENST00000369850 / NM_001110556.2; = p.S2205= on NM_001456.3) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1358869497, CD012847, COSV100774506; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNC | c.585C>T p.H195= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as rs1179524112, COSV100405470; called by muse, mutect2, varscan2
